Somatic mutation profile of tumor specimen C3N-02026-02 (aliquot CPT0133230009) from CPTAC case C3N-02026, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.5 years (29,420 days).
Specimen C3N-02026-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f74d1b0c-2fe6-48bc-8aa7-347c809c9a54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02026-71 (Blood Derived Normal), aliquot CPT0133340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f7d9546-40b4-4d39-8b52-6a554beac4c0

The open-access MAF lists 307 somatic variants for this specimen: 193 protein-altering or splice-affecting, 100 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 100, Nonsense Mutation 13, Intron 7, Frame Shift Ins 2, 3'Flank 2, RNA 2, Splice Region 1, 5'Flank 1, 3'UTR 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 211/376 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABLIM2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs747552782; called by muse, varscan2
- ADAM29 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 175/401 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV63666072; called by muse, mutect2, varscan2
- ADAMTS14 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 158/282 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as COSV100941854; called by muse, mutect2, varscan2
- ADGRB3 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 54/413 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs764710020, COSV53234852, COSV99483148; called by muse, mutect2, varscan2
- ANKRD30A | c.2644C>T p.P882S (on ENST00000611781; = p.P826S on NM_052997.2) | Missense Mutation (SNP) | VAF 126/257 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); catalogued as rs1219901612; called by muse, mutect2, varscan2
- ANO2 | c.964G>A p.D322N (on ENST00000356134 / NM_001278597.3; = p.D326N on NM_001278596.3) | Missense Mutation (SNP) | VAF 188/550 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs781540782, COSV59007575; called by muse, mutect2, varscan2
- ATP13A5 | c.2656C>T p.Q886* | Nonsense Mutation (SNP) | VAF 77/272 reads (28%) | catalogued as rs776794032; called by muse, mutect2, varscan2
- ATP2C2 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750950827; called by muse, mutect2, varscan2
- ATP7B | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 31/634 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs2277447, COSV54438206; called by muse, mutect2
- ATPAF2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 102/406 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV58264716; called by muse, mutect2, varscan2
- BDKRB2 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 184/362 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV60013477; called by muse, varscan2
- BEND4 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 100/456 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs552724030; called by mutect2, varscan2
- CLCA4 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 102/381 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV65283411; called by muse, mutect2, varscan2
- CSMD1 | c.2192C>T p.T731I (on ENST00000520002; = p.T730I on NM_033225.6) | Missense Mutation (SNP) | VAF 82/464 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1046613428; called by muse, mutect2, varscan2
- DARS1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 110/242 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as rs768482329, COSV51539943; called by muse, varscan2
- DNAH1 | c.5302C>T p.L1768F | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750764706, COSV101325071; called by muse, mutect2, varscan2
- ENAM | c.3203C>T p.S1068F | Missense Mutation (SNP) | VAF 49/356 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs746274747; called by muse, mutect2, varscan2
- EPPK1 | c.5021G>A p.R1674Q | Missense Mutation (SNP) | VAF 399/992 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as rs546299644; called by muse, mutect2, varscan2
- EREG | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199234668; called by muse, mutect2, varscan2
- FAM47B | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 128/507 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100264679; called by muse, mutect2, varscan2
- FAT4 | c.4973G>A p.G1658E | Missense Mutation (SNP) | VAF 151/382 reads (40%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV67881023; called by muse, mutect2, varscan2
- FDPS | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 84/583 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs11556432; called by muse, mutect2, varscan2
- FGD2 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 380/772 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1419929674; called by muse, mutect2, varscan2
- GCN1 | c.3545C>T p.A1182V | Missense Mutation (SNP) | VAF 112/588 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1389877494; called by muse, mutect2, varscan2
- IGHV4-34 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs1225483401; called by muse, mutect2, varscan2
- IL1RL1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs867114006, COSV52119033; called by muse, mutect2
- IMPG2 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as COSV51986912; called by muse, mutect2, varscan2
- INSL6 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 95/467 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV67562447; called by muse, mutect2, varscan2
- INTS7 | c.1055G>A p.C352Y | Missense Mutation (SNP) | VAF 362/462 reads (78%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.568); catalogued as rs1337767322; called by muse, mutect2, varscan2
- ITGB6 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.447); catalogued as rs770567732, COSV51794155; called by muse, mutect2, varscan2
- KAT6B | c.5390G>A p.R1797Q | Missense Mutation (SNP) | VAF 185/330 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs777556102; called by muse, mutect2, varscan2
- KCNJ10 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 70/737 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514673, CM105040, COSV100927976; ClinVar: uncertain significance; called by muse, mutect2
- KCNK4 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533333432; called by muse, mutect2, varscan2
- KCNQ3 | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 147/426 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0.3); catalogued as rs943073757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD5 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 35/261 reads (13%) | catalogued as rs756594781, COSV57064149; called by muse, mutect2, varscan2
- KLHL3 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 87/345 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.057); catalogued as rs559251218, COSV59051298; called by muse, mutect2, varscan2
- KRTAP5-1 | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 44/104 reads (42%) | catalogued as rs1482370518; called by mutect2, varscan2
- LILRB1 | c.1648G>A p.D550N (on ENST00000427581; = p.D500N on NM_006669.6) | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV61115913, COSV61117763; called by muse, mutect2, varscan2
- MAP3K10 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 213/554 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs756190259; called by muse, varscan2
- MDH1B | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV100982239, COSV65589094; called by muse, mutect2, varscan2
- MGAT5B | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 105/426 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs912752305; called by muse, mutect2, varscan2
- MLXIP | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780988464; called by muse, mutect2
- MUC16 | c.34158A>C p.E11386D | Missense Mutation (SNP) | VAF 37/560 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); catalogued as COSV67442926; called by muse, mutect2
- MXRA5 | c.8095C>T p.R2699C | Missense Mutation (SNP) | VAF 144/484 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54252600; called by muse, mutect2, varscan2
- NCOA3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 49/662 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs145438835; called by muse, mutect2
- NLRP14 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs372852266; called by muse, mutect2, varscan2
- OR2L3 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 64/394 reads (16%) | catalogued as rs375596625; called by muse, mutect2, varscan2
- OR2T10 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 110/411 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs201301575, COSV57897177; called by muse, mutect2, varscan2
- OR2V1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs528083565, COSV61459550; called by muse, mutect2, varscan2
- OR4D6 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs191765580; called by muse, mutect2, varscan2
- OR4N5 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267603919, COSV61320026; called by muse, mutect2, varscan2
- OR51D1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 109/368 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as rs375185822; called by muse, mutect2, varscan2
- OR5G3 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 71/261 reads (27%) | catalogued as rs1396036814; called by muse, mutect2, varscan2
- OTX2 | c.852G>A p.W284* (on ENST00000408990 / NM_172337.3; = p.W292* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 30/272 reads (11%) | catalogued as COSV59767086; called by muse, mutect2
- PCDHB13 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV99507559; called by muse, mutect2, varscan2
- PDE11A | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV99035994; called by muse, mutect2, varscan2
- PDE6C | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139251833; called by muse, mutect2, varscan2
- PHTF1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.24); catalogued as COSV99793621; called by muse, mutect2, varscan2
- PKIA | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1309067245; called by muse, mutect2, varscan2
- PRDM11 | c.700G>A p.A234T (on ENST00000530656 / NM_001359633.1; = p.A200T on NM_001256695.1) | Missense Mutation (SNP) | VAF 70/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1310111430; called by muse, mutect2, varscan2
- RELN | c.5194C>T p.L1732F | Missense Mutation (SNP) | VAF 196/385 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs755485060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS21 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 163/247 reads (66%) | SIFT tolerated (0.51); PolyPhen benign (0.415); catalogued as COSV101314001; called by muse, mutect2, varscan2
- RPS27AP5 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 380/520 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs775452831; called by muse, varscan2
- SECISBP2L | c.2908G>A p.D970N (on ENST00000559471 / NM_001193489.2; = p.D925N on NM_014701.4) | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.631); catalogued as COSV55934943; called by muse, mutect2, varscan2
- SETMAR | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 155/283 reads (55%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.024); catalogued as rs968658005, COSV100740917; called by muse, mutect2, varscan2
- SHISA3 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 111/332 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371970488; called by muse, mutect2, varscan2
- SLC35F4 | c.1465G>A p.E489K (on ENST00000339762 / NM_001352015.2; = p.E453K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV60264354; called by muse, mutect2, varscan2
- SLC39A2 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 202/410 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.028); catalogued as rs755435446; called by muse, mutect2, varscan2
- SLIT3 | c.1747G>C p.V583L | Missense Mutation (SNP) | VAF 112/376 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.993); catalogued as COSV60598217; called by muse, mutect2, varscan2
- SLIT3 | c.1746C>A p.S582R | Missense Mutation (SNP) | VAF 112/374 reads (30%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.797); catalogued as COSV100265859; called by muse, mutect2, varscan2
- SPCS1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 224/368 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV51777353; called by muse, mutect2, varscan2
- STOML3 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 174/535 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV65510198; called by muse, mutect2, varscan2
- SYNDIG1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 300/453 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as COSV65234238, COSV65234465; called by mutect2, varscan2
- TENM4 | c.6177G>T p.Q2059H | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV53646100; called by mutect2, varscan2
- TIAM1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 135/433 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54539611; called by muse, mutect2, varscan2
- TMEM176A | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 72/422 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as rs750447907, COSV50241487; called by muse, mutect2, varscan2
- TRBV4-2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 34/718 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462761444; called by muse, mutect2
- TRIM49 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV100315860; called by muse, mutect2, varscan2
- TTC23L | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1314476247, COSV72205791, COSV72205833; called by muse, mutect2, varscan2
- TTN | c.68924G>A p.R22975Q (on ENST00000591111; = p.R15551Q on NM_003319.4) | Missense Mutation (SNP) | VAF 157/372 reads (42%) | PolyPhen possibly damaging (0.786); catalogued as rs201694149, COSV100621370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.15107G>A p.R5036Q (on ENST00000591111; = p.R4109Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/213 reads (14%) | PolyPhen possibly damaging (0.873); catalogued as rs751653047, COSV60061976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXK | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs373706876; called by muse, mutect2, varscan2
- UNC13C | c.5941G>T p.V1981F | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as COSV52915499; called by muse, mutect2
- USP9X | c.2545C>T p.R849* | Nonsense Mutation (SNP) | VAF 148/409 reads (36%) | catalogued as COSV61074374; called by muse, mutect2, varscan2
- VWF | c.5777C>T p.S1926L | Missense Mutation (SNP) | VAF 77/553 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs375136778; called by muse, mutect2, varscan2
- ZCCHC12 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59571304; called by muse, mutect2, varscan2
- ZFP36L2 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs373300759; called by muse, mutect2, varscan2
- ZNF750 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 106/636 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs778933111, COSV53962453; called by muse, mutect2, varscan2
- ZSCAN20 | c.1421C>A p.P474Q | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as COSV100792785; called by muse, mutect2, varscan2
- ABCB4 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADAD1 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.5052C>G p.S1684R | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFF3 | c.3314C>T p.S1105F | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALDH9A1 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- AMPD2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANAPC7 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ANO1 | c.1886A>C p.K629T | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ARVCF | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 321/909 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BAZ2B | c.3328G>T p.D1110Y | Missense Mutation (SNP) | VAF 51/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BICDL1 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 132/409 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRINP1 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 146/340 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 86/468 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CAPN8 | c.364T>A p.Y122N | Missense Mutation (SNP) | VAF 102/520 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- CD33 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- CDKAL1 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 40/663 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, mutect2
- CELF5 | c.1156C>G p.P386A | Missense Mutation (SNP) | VAF 29/490 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2
- CENPV | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 118/562 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CEP78 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CFAP299 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CGB5 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 53/610 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCN5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 112/410 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CLIC6 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 130/444 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CRYBB1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 380/502 reads (76%) | SIFT tolerated (0.18); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CRYBG2 | c.3640G>A p.G1214S | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DDN | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 126/668 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.341); called by muse, varscan2
- DHX29 | c.293T>A p.I98N | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DHX38 | c.3374C>T p.T1125I | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DLGAP5 | c.1967T>C p.I656T | Missense Mutation (SNP) | VAF 159/310 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DMBT1 | c.5152C>T p.P1718S (on ENST00000338354 / NM_001377530.1; = p.P961S on NM_004406.3) | Missense Mutation (SNP) | VAF 136/397 reads (34%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- DUSP6 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 267/630 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ECEL1 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ERICH6 | c.1562G>A p.W521* | Nonsense Mutation (SNP) | VAF 219/343 reads (64%) | called by muse, mutect2, varscan2
- FAM47E | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- FANCC | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 253/532 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- FBXO5 | c.979T>G p.S327A | Missense Mutation (SNP) | VAF 99/283 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- FREM1 | c.5381C>T p.P1794L | Missense Mutation (SNP) | VAF 140/365 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- FRY | c.1350G>T p.M450I | Missense Mutation (SNP) | VAF 52/485 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FUT9 | c.956G>T p.R319M | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GAL3ST1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 523/670 reads (78%) | SIFT tolerated (0.34); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GIPC3 | c.3941C>T p.P1314L | Missense Mutation (SNP) | VAF 125/419 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- GPR108 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 156/428 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GSDMC | c.1436A>G p.N479S | Missense Mutation (SNP) | VAF 155/462 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HECTD4 | c.1757C>A p.A586D | Missense Mutation (SNP) | VAF 42/496 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HEPHL1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.11873G>A p.G3958E | Missense Mutation (SNP) | VAF 118/443 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1-17 | c.62G>T p.R21M | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- IGLV1-44 | c.205T>A p.Y69N | Missense Mutation (SNP) | VAF 52/738 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- IGLV1-51 | c.69G>C p.L23F | Missense Mutation (SNP) | VAF 18/658 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- IQCJ-SCHIP1 | c.1270G>A p.E424K (on ENST00000485419 / NM_001197113.1; = p.E348K on NM_014575.3) | Missense Mutation (SNP) | VAF 185/302 reads (61%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ITGAL | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 46/250 reads (18%) | called by muse, mutect2, varscan2
- ITGB1 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KRT82 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- LIN9 | c.502C>G p.P168A (on ENST00000366808 / NM_001270410.2; = p.P113A on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2
- LMLN2 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 154/280 reads (55%) | SIFT tolerated (0.96); called by muse, mutect2, varscan2
- MAB21L2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 155/356 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- MAGEA11 | c.1081C>A p.Q361K | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by mutect2, varscan2
- MCTP2 | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 143/432 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MMP28 | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 154/661 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MS4A18 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MXRA8 | c.1223-7C>T | Splice Region (SNP) | VAF 48/205 reads (23%) | called by muse, mutect2, varscan2
- NETO1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP9 | c.2402T>C p.L801P | Missense Mutation (SNP) | VAF 71/466 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- NOD2 | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 116/512 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- NRG1 | c.1081G>A p.E361K (on ENST00000405005 / NM_013964.5; = p.E366K on NM_013956.5) | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- OMG | c.1162A>C p.N388H | Missense Mutation (SNP) | VAF 170/413 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- OR2T3 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 94/592 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, varscan2
- OR2Z1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 106/535 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OTOG | c.4409G>A p.W1470* | Nonsense Mutation (SNP) | VAF 66/244 reads (27%) | called by muse, mutect2, varscan2
- PCDH9 | c.410A>T p.D137V | Missense Mutation (SNP) | VAF 88/428 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PICK1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 386/490 reads (79%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PREX1 | c.4355C>T p.P1452L | Missense Mutation (SNP) | VAF 128/601 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKG2 | c.1552_1553insT p.R518Lfs*7 | Frame Shift Ins (INS) | VAF 44/224 reads (20%) | called by mutect2, pindel*, varscan2
- RFC1 | c.3338C>T p.A1113V (on ENST00000381897 / NM_001363496.2; = p.A1112V on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2
- RP1 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 61/417 reads (15%) | called by muse, mutect2, varscan2
- RPS27AP5 | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 80/545 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.221); called by muse, varscan2
- RTL9 | c.731A>G p.K244R | Missense Mutation (SNP) | VAF 136/420 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEL1L3 | c.803C>G p.P268R | Missense Mutation (SNP) | VAF 125/388 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SHROOM4 | c.3613C>T p.Q1205* | Nonsense Mutation (SNP) | VAF 96/413 reads (23%) | called by muse, mutect2, varscan2
- SLAMF9 | c.640dup p.I214Nfs*3 | Frame Shift Ins (INS) | VAF 321/544 reads (59%) | called by mutect2, pindel, varscan2
- SLC25A35 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 198/526 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC26A8 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 124/652 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- SMCR8 | c.566A>T p.K189M | Missense Mutation (SNP) | VAF 137/457 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SMYD3 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 394/517 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAG16 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SPSB2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 211/609 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRCAP | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 159/666 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SRSF7 | c.405T>A p.H135Q | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ST18 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 79/524 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SULT1A2 | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TAP2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 144/770 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by mutect2, varscan2
- TMEM233 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 96/528 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- TMEM26 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 67/255 reads (26%) | called by muse, mutect2, varscan2
- TRIM66 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, varscan2
- TRPA1 | c.2350G>T p.G784W | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- USP31 | c.2719G>C p.V907L | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WDFY4 | c.4819C>A p.Q1607K | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF420 | c.1756C>A p.P586T | Missense Mutation (SNP) | VAF 53/586 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF490 | c.1015T>G p.C339G | Missense Mutation (SNP) | VAF 46/628 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2
- ZNF541 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 93/588 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF610 | c.1275G>T p.E425D | Missense Mutation (SNP) | VAF 104/576 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNFX1 | c.5269C>T p.R1757* | Nonsense Mutation (SNP) | VAF 270/698 reads (39%) | called by muse, mutect2, varscan2
- ZSCAN25 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 135/601 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ACTA2 | c.843C>T p.Y281= | Silent (SNP) | VAF 122/226 reads (54%) | called by muse, mutect2, varscan2
- ADGRB1 | c.4185C>T p.S1395= | Silent (SNP) | VAF 39/238 reads (16%) | called by muse, mutect2, varscan2
- ADGRG4 | c.1935T>C p.A645= | Silent (SNP) | VAF 124/476 reads (26%) | called by muse, mutect2, varscan2
- AHCYL2 | c.1212G>A p.G404= | Silent (SNP) | VAF 141/396 reads (36%) | catalogued as rs746216857; called by muse, mutect2, varscan2
- ARHGEF1 | c.2520G>C p.P840= | Silent (SNP) | VAF 87/515 reads (17%) | catalogued as rs782619422; called by muse, mutect2, varscan2
- ARHGEF15 | c.2380C>T p.L794= | Silent (SNP) | VAF 118/340 reads (35%) | catalogued as rs777602993; called by muse, mutect2, varscan2
- ATP13A1 | c.3261C>T p.F1087= | Silent (SNP) | VAF 58/375 reads (15%) | catalogued as rs145819449; called by muse, mutect2, varscan2
- BEGAIN | c.273G>A p.A91= | Silent (SNP) | VAF 47/351 reads (13%) | catalogued as rs747563702, COSV62068243; called by muse, mutect2, varscan2
- BEND3 | c.1512G>T p.L504= | Silent (SNP) | VAF 116/400 reads (29%) | catalogued as rs1554231557; called by muse, mutect2, varscan2
- CCDC185 | c.1551C>A p.A517= | Silent (SNP) | VAF 81/584 reads (14%) | called by muse, mutect2, varscan2
- CD200R1L | c.135G>A p.L45= | Silent (SNP) | VAF 115/189 reads (61%) | called by muse, mutect2, varscan2
- CD244 | c.540G>A p.G180= (on ENST00000368033 / NM_001166663.2; = p.G175= on NM_016382.4) | Silent (SNP) | VAF 110/563 reads (20%) | catalogued as rs749059531; called by muse, mutect2, varscan2
- CD53 | c.659G>A p.*220= | Silent (SNP) | VAF 61/203 reads (30%) | called by muse, mutect2, varscan2
- CDC16 | c.1110T>C p.P370= | Silent (SNP) | VAF 107/305 reads (35%) | called by muse, mutect2, varscan2
- CDC42BPG | c.3225C>T p.P1075= | Silent (SNP) | VAF 138/494 reads (28%) | catalogued as rs1257092189; called by muse, mutect2, varscan2
- CDH8 | c.1713C>T p.V571= | Silent (SNP) | VAF 84/414 reads (20%) | called by muse, mutect2, varscan2
- CDK5RAP1 | c.471C>T p.N157= | Silent (SNP) | VAF 256/662 reads (39%) | called by muse, mutect2, varscan2
- CEP250 | c.114C>T p.S38= | Silent (SNP) | VAF 297/753 reads (39%) | called by muse, mutect2, varscan2
- CERK | c.753C>T p.T251= | Silent (SNP) | VAF 140/646 reads (22%) | called by muse, mutect2, varscan2
- COL6A5 | c.7332C>T p.S2444= (on ENST00000312481; = p.S2440= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 166/279 reads (59%) | called by muse, mutect2, varscan2
- CRYBG2 | c.2691C>G p.G897= | Silent (SNP) | VAF 99/352 reads (28%) | called by muse, mutect2, varscan2
- CSE1L | c.2541C>T p.T847= | Silent (SNP) | VAF 165/474 reads (35%) | called by muse, mutect2, varscan2
- DAPK3 | c.1065G>A p.A355= | Silent (SNP) | VAF 142/466 reads (30%) | catalogued as rs1230717935, COSV56664028; called by muse, mutect2, varscan2
- DCST1 | c.1281G>A p.R427= | Silent (SNP) | VAF 60/356 reads (17%) | catalogued as COSV55056568; called by muse, mutect2, varscan2
- DLK1 | c.795C>T p.A265= | Silent (SNP) | VAF 60/438 reads (14%) | called by muse, mutect2, varscan2
- DPP9 | c.1290C>T p.F430= (on ENST00000598800; = p.F459= on NM_139159.5) | Silent (SNP) | VAF 132/358 reads (37%) | called by muse, mutect2, varscan2
- ERCC6L | c.3564T>G p.S1188= | Silent (SNP) | VAF 39/427 reads (9%) | called by muse, mutect2
- ERN2 | c.654G>A p.T218= | Silent (SNP) | VAF 107/512 reads (21%) | catalogued as rs146682258; called by muse, mutect2, varscan2
- EXD3 | c.75C>T p.L25= | Silent (SNP) | VAF 157/359 reads (44%) | catalogued as rs1299737578; called by muse, mutect2, varscan2
- FLNC | c.4782G>A p.G1594= | Silent (SNP) | VAF 108/602 reads (18%) | catalogued as COSV100367461; called by muse, mutect2, varscan2
- GRIN2B | c.2910C>T p.F970= | Silent (SNP) | VAF 205/509 reads (40%) | catalogued as rs201252525; called by muse, mutect2, varscan2
- HTR1E | c.579C>T p.I193= | Silent (SNP) | VAF 55/385 reads (14%) | catalogued as rs753830899; called by muse, mutect2, varscan2
- IGKV1-12 | c.249G>A p.R83= | Silent (SNP) | VAF 117/550 reads (21%) | catalogued as rs1348287135; called by muse, mutect2
- INHA | c.957C>T p.S319= | Silent (SNP) | VAF 55/371 reads (15%) | called by muse, mutect2, varscan2
- INTS6L | c.1875G>A p.R625= | Silent (SNP) | VAF 94/402 reads (23%) | called by muse, mutect2, varscan2
- IQSEC1 | c.93G>A p.E31= | Silent (SNP) | VAF 168/312 reads (54%) | called by muse, mutect2, varscan2
- ITGA5 | c.2199G>A p.L733= | Silent (SNP) | VAF 148/435 reads (34%) | called by muse, mutect2, varscan2
- KDR | c.3774G>A p.T1258= | Silent (SNP) | VAF 68/285 reads (24%) | catalogued as rs779352139; called by muse, mutect2, varscan2
- KLHL14 | c.232C>T p.L78= | Silent (SNP) | VAF 303/515 reads (59%) | called by muse, mutect2, varscan2
- KRT82 | c.639C>T p.S213= | Silent (SNP) | VAF 135/431 reads (31%) | called by muse, mutect2, varscan2
- LIMK1 | c.114C>T p.L38= | Silent (SNP) | VAF 238/497 reads (48%) | catalogued as rs1204834024; called by muse, mutect2, varscan2
- LRRC72 | c.21C>T p.P7= | Silent (SNP) | VAF 364/724 reads (50%) | catalogued as rs1450845951; called by muse, mutect2
- MAPK8IP3 | c.3147C>T p.I1049= | Silent (SNP) | VAF 107/469 reads (23%) | catalogued as COSV51602970; called by muse, mutect2, varscan2
- MMP1 | c.1314C>T p.F438= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as COSV59510730; called by muse, mutect2, varscan2
- MUC16 | c.36540C>T p.T12180= | Silent (SNP) | VAF 107/308 reads (35%) | called by muse, mutect2, varscan2
- MUC7 | c.1101A>C p.L367= | Silent (SNP) | VAF 42/177 reads (24%) | called by muse, mutect2, varscan2
- MYH4 | c.1698C>T p.F566= | Silent (SNP) | VAF 188/507 reads (37%) | catalogued as rs746159729, COSV55112281; called by muse, mutect2, varscan2
- NAV2 | c.1059C>T p.S353= (on ENST00000396087 / NM_001244963.2; = p.S330= on NM_145117.5) | Silent (SNP) | VAF 125/335 reads (37%) | called by muse, mutect2, varscan2
- NBPF3 | c.1818C>T p.A606= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- NEXMIF | c.3672G>A p.K1224= | Silent (SNP) | VAF 153/597 reads (26%) | called by muse, mutect2, varscan2
- NPC1L1 | c.3861C>T p.V1287= | Silent (SNP) | VAF 47/439 reads (11%) | catalogued as rs780659447, COSV99202780; called by muse, mutect2, varscan2
- NR2F1 | c.1257C>T p.S419= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as rs902206590; called by muse, mutect2, varscan2
- ODF4 | c.699G>A p.R233= | Silent (SNP) | VAF 181/473 reads (38%) | called by muse, mutect2, varscan2
- OPRK1 | c.729C>T p.I243= | Silent (SNP) | VAF 185/527 reads (35%) | catalogued as rs1413016291, COSV55575408; called by muse, mutect2, varscan2
- OR11G2 | c.222C>T p.L74= | Silent (SNP) | VAF 43/346 reads (12%) | catalogued as COSV62131773, COSV62132324; called by muse, mutect2, varscan2
- OR2G2 | c.726G>A p.G242= | Silent (SNP) | VAF 351/459 reads (76%) | catalogued as COSV60740284; called by muse, mutect2, varscan2
- OR51F1 | c.450C>T p.I150= | Silent (SNP) | VAF 74/265 reads (28%) | catalogued as COSV58578752; called by muse, mutect2, varscan2
- OSMR | c.240C>T p.I80= | Silent (SNP) | VAF 43/235 reads (18%) | called by muse, mutect2, varscan2
- PCDHA8 | c.2319C>T p.S773= | Silent (SNP) | VAF 108/381 reads (28%) | catalogued as COSV65329433; called by muse, mutect2, varscan2
- PCYT1A | c.600C>T p.I200= | Silent (SNP) | VAF 188/296 reads (64%) | catalogued as COSV53057223, COSV99492009; called by muse, mutect2, varscan2
- PGK2 | c.769C>T p.L257= | Silent (SNP) | VAF 169/529 reads (32%) | catalogued as rs1337705044, COSV59162992; called by muse, mutect2, varscan2
- PLXNA4 | c.3507C>T p.I1169= | Silent (SNP) | VAF 58/408 reads (14%) | catalogued as rs372392636, COSV58117025; called by muse, mutect2, varscan2
- PRAMEF12 | c.1105C>T p.L369= | Silent (SNP) | VAF 122/475 reads (26%) | called by muse, mutect2, varscan2
- PSMG1 | c.585G>A p.Q195= | Silent (SNP) | VAF 127/425 reads (30%) | called by muse, mutect2, varscan2
- PTPRT | c.4209C>T p.I1403= | Silent (SNP) | VAF 255/653 reads (39%) | catalogued as rs868408776, COSV62010451; called by muse, mutect2, varscan2
- RAB40B | c.393G>A p.A131= | Silent (SNP) | VAF 60/774 reads (8%) | catalogued as rs769582459, COSV53916677; called by muse, mutect2
- RALGAPA2 | c.3252C>T p.A1084= | Silent (SNP) | VAF 74/313 reads (24%) | catalogued as rs762230375, COSV52490703; called by muse, mutect2, varscan2
- RELB | c.1056C>T p.D352= | Silent (SNP) | VAF 87/464 reads (19%) | catalogued as rs202054363; ClinVar: likely benign; called by muse, mutect2, varscan2
- RIPOR2 | c.1737C>T p.A579= | Silent (SNP) | VAF 50/832 reads (6%) | catalogued as rs765588591; called by muse, mutect2
- RPS6KB2 | c.765G>T p.L255= | Silent (SNP) | VAF 108/436 reads (25%) | called by muse, mutect2, varscan2
- RRH | c.516T>G p.G172= | Silent (SNP) | VAF 65/292 reads (22%) | called by muse, mutect2, varscan2
- SCNN1G | c.171C>T p.I57= | Silent (SNP) | VAF 140/600 reads (23%) | catalogued as COSV55597381; called by muse, mutect2, varscan2
- SEMA3C | c.1155C>T p.P385= | Silent (SNP) | VAF 53/361 reads (15%) | called by muse, mutect2, varscan2
- SEMA4C | c.651C>T p.G217= | Silent (SNP) | VAF 104/277 reads (38%) | catalogued as rs1031981582, COSV59690186; called by muse, mutect2, varscan2
- SFMBT1 | c.1191C>T p.L397= | Silent (SNP) | VAF 79/288 reads (27%) | catalogued as COSV56253991; called by muse, mutect2, varscan2
- SH2D1A | c.126C>T p.C42= | Silent (SNP) | VAF 72/288 reads (25%) | catalogued as CM002854; called by muse, mutect2, varscan2
- SHISA9 | c.363C>A p.T121= | Silent (SNP) | VAF 93/529 reads (18%) | called by muse, mutect2, varscan2
- SLC22A10 | c.1137C>T p.F379= | Silent (SNP) | VAF 102/326 reads (31%) | catalogued as rs564171817, COSV60419818; called by muse, mutect2, varscan2
- SLC30A5 | c.1218A>C p.S406= | Silent (SNP) | VAF 80/247 reads (32%) | called by muse, mutect2, varscan2
- SLC39A13 | c.810C>T p.L270= | Silent (SNP) | VAF 89/353 reads (25%) | catalogued as rs372659943; called by muse, mutect2, varscan2
- SLITRK2 | c.1656C>T p.I552= | Silent (SNP) | VAF 120/507 reads (24%) | catalogued as COSV59427563; called by muse, mutect2, varscan2
- SPCS1 | c.54C>T p.S18= | Silent (SNP) | VAF 226/368 reads (61%) | catalogued as rs1478959356; called by muse, mutect2, varscan2
- SPTB | c.4722C>T p.A1574= | Silent (SNP) | VAF 61/474 reads (13%) | catalogued as rs757295073, COSV67633897; called by muse, mutect2, varscan2
- SZT2 | c.2685C>T p.A895= | Silent (SNP) | VAF 75/312 reads (24%) | called by muse, mutect2, varscan2
- TEFM | c.291C>T p.I97= | Silent (SNP) | VAF 62/371 reads (17%) | catalogued as rs201209638, COSV60091789; called by muse, mutect2, varscan2
- TENM4 | c.1008C>T p.Y336= | Silent (SNP) | VAF 109/366 reads (30%) | called by muse, mutect2, varscan2
- THSD7B | c.927T>C p.S309= | Silent (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- TRMT44 | c.2019C>T p.L673= | Silent (SNP) | VAF 97/433 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.46467A>G p.G15489= (on ENST00000591111; = p.G8065= on NM_003319.4) | Silent (SNP) | VAF 79/288 reads (27%) | called by muse, mutect2, varscan2
- UGT1A1 | c.384C>T p.S128= | Silent (SNP) | VAF 96/258 reads (37%) | called by muse, varscan2
- USF2 | c.876G>A p.Q292= | Silent (SNP) | VAF 211/561 reads (38%) | called by muse, mutect2, varscan2
- USP26 | c.2457G>A p.K819= | Silent (SNP) | VAF 122/426 reads (29%) | called by muse, mutect2, varscan2
- VGF | c.1323G>A p.E441= | Silent (SNP) | VAF 253/945 reads (27%) | called by muse, mutect2, varscan2
- VIRMA | c.252C>T p.F84= | Silent (SNP) | VAF 113/399 reads (28%) | catalogued as rs369924461; called by muse, mutect2, varscan2
- WDFY4 | c.5169C>T p.T1723= | Silent (SNP) | VAF 193/353 reads (55%) | catalogued as rs1306686822; called by muse, mutect2, varscan2
- YY2 | c.957G>A p.G319= | Silent (SNP) | VAF 112/455 reads (25%) | called by muse, mutect2, varscan2
- ZCCHC12 | c.759G>A p.P253= | Silent (SNP) | VAF 93/392 reads (24%) | catalogued as COSV59571485; called by muse, mutect2, varscan2
- ZFPM2 | c.984C>T p.F328= | Silent (SNP) | VAF 122/299 reads (41%) | catalogued as rs1283514848, COSV65874556, COSV65876569; called by muse, mutect2, varscan2
- ZNF229 | c.1029T>G p.P343= | Silent (SNP) | VAF 31/591 reads (5%) | called by muse, mutect2
- ZP3 | c.1104G>A p.L368= (on ENST00000394857 / NM_001110354.2; = p.L317= on NM_007155.6) | Silent (SNP) | VAF 73/612 reads (12%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.2522-3519G>T | Intron (SNP) | VAF 42/365 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916457 G>A | 5'Flank (SNP) | VAF 60/375 reads (16%) | catalogued as rs1278169968, COSV100388398; called by muse, mutect2, varscan2
- CLCN7 | c.*162C>G | 3'UTR (SNP) | VAF 145/530 reads (27%) | called by muse, mutect2, varscan2
- CYLD | c.-36C>T | 5'UTR (SNP) | VAF 148/338 reads (44%) | catalogued as rs1183633894; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+524A>G | Intron (SNP) | VAF 57/367 reads (16%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+12325_1514+12334del | Intron (DEL) | VAF 26/92 reads (28%) | called by muse*, pindel, varscan2
- LINC00968 | n.210G>A | RNA (SNP) | VAF 111/348 reads (32%) | catalogued as rs1414625505; called by muse, mutect2, varscan2
- MACF1 | c.15832-8519C>T | Intron (SNP) | VAF 119/438 reads (27%) | called by muse, mutect2, varscan2
- NDUFA11 | chr19:5893129 C>A | 3'Flank (SNP) | VAF 101/583 reads (17%) | called by muse, mutect2, varscan2
- PDLIM2 | chr8:22594551 G>A | 3'Flank (SNP) | VAF 131/345 reads (38%) | catalogued as rs373037513; called by muse, mutect2, varscan2
- SLC22A17 | n.957C>G | RNA (SNP) | VAF 102/433 reads (24%) | called by muse, mutect2, varscan2
- TNNT3 | c.715-740G>T | Intron (SNP) | VAF 38/325 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.10303+2297G>A | Intron (SNP) | VAF 51/271 reads (19%) | catalogued as rs1408667459, COSV59903105; called by muse, mutect2, varscan2
- ZNF174 | c.625+46C>T | Intron (SNP) | VAF 97/481 reads (20%) | called by muse, mutect2, varscan2
